Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A83G, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A83G-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME:		SURG PATH #:
MR #:		SPECIMEN CLASS:
BILLING #:		ALT ID #:
LOCATION:		DATE OF PROCEDURE:
AGE:	SEX: M	DATE RECEIVED:
DOB:		TIME RECEIVED:
PHYSICIAN:		DATE OF REPORT:
COPY TO:		DATE OF PRINTING:

Material Received:

A: left pelvic lymph nodes
B: right pelvic lymph node
C: prostate in study

History:

-year-old male with prostate cancer.

ICD-O-3
Adenocarcinoma NOS 8140/3
Prostate NOS C61.9
JW 11/16/14

Final Diagnosis:

- A. Lymph node (1), "left pelvic lymph nodes", biopsy:
There is no evidence of malignancy in one lymph node (0/1).
- B. Lymph nodes (3), "right pelvic lymph node", biopsy:
There is no evidence of malignancy in three lymph node (0/3).
- C. Prostate, "prostate in study", prostatectomy:
Prostatic adenocarcinoma, Gleason score 4+3 (score 7/10), involving 90% of the tissue, and involving the right distal urethral margin and bilateral lateral margins. See comment.

Comment:

PROSTATE CANCER CHECKLIST:

Procedure: Prostatectomy

Histologic Type: Adenocarcinoma

Histologic Grade: Moderately-differentiated

Gleason Pattern

Primary Pattern: 4

Secondary Pattern: 3

Tertiary Pattern: 5

Total Gleason Score: 7/10

Proportion (percentage) of prostatic tissue involved by tumor: 90%

Extraprostatic Extension: Present (tumor involves extraprostatic fat and seminal vesicles)

Seminal Vesicle Invasion: Present

Margins: Right distal urethral margin, and bilateral lateral margins involved by carcinoma

Treatment Effect on Carcinoma: Not identified

Lymph-Vascular Invasion: Not identified

Lymph Nodes:

Number Examined: 4

Number Involved: 0

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Size of largest lymph node metastasis: Not applicable

Perineural Invasion: Present

Additional Pathologic Findings: None

Pathologic Staging (pTNM):

pT3bN0M(not applicable)

Primary Tumor (pT)

pT3b: Seminal vesicle invasion

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the Quality Assurance Program at _____ this case has been concurrently reviewed by the following pathologist: _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Interpreted by:

Electronically Signed Out By

MD, Attending Physician

M.D. Resident

Gross Description:

A. Received fresh labeled with the patient's name and "left pelvic lymph node" is a 2.8 x 2.5 x 1.0 cm piece of red-yellow tissue. The specimen is palpated to reveal one possible lymph node measuring 1.5 x 1.0 x 0.4 cm. The lymph node is bisected and submitted entirely as A1FS.

B. Received fresh labeled with the patient's name and "right pelvic lymph nodes" are two pieces of red-yellow fibroadipose tissue measuring 2.3 x 2.0 x 1.0 cm and 2.5 x 2.2 x 1.0 cm. The specimen is palpated to reveal three possible lymph nodes measuring 2.0 x 1.6 x 0.7 cm, 0.6 x 0.4 x 0.3 cm and 3.0 x 1.0 x 0.4 cm. The two larger lymph nodes are bisected and the specimen is submitted entirely as frozen section diagnosis as B1FS and B2FS.

C. Received fresh, labeled with the patient's name and "prostate" is a 56 gram prostatectomy specimen measuring 5.0 cm from left to right, 4.0 cm from anterior to posterior, and 4.9 cm from superior to inferior. The attached right seminal vesicle measures 3.3 x 2.0 x 0.8 cm, the right vas deferens measures 2.5 cm in length and 0.9 cm in diameter, the left vas deferens measures 3.0 cm in length and 0.9 cm in diameter and the left seminal vesicle measures 2.7 x 1.8 x 0.8 cm. The external surface of the prostate is red-brown and ragged. The right side of the prostate is inked black and the left side is inked orange. The prostate is serially sectioned to reveal a grossly nodular appearance. The remainder of the cut surface is tan-brown and glistening. The specimen is submitted as follows:

- C1 Right bladder neck margin (serially sectioned).
- C2 Left bladder neck margin (serially sectioned).
- C3 Right distal urethral margin (serially sectioned).
- C4 Left distal urethral margins (serially sectioned).
- C5 Right and left seminal vesicle and vas deferens margins. C6 Representative section from the right mid-anterior prostate.
- C7 Representative section from the left mid-anterior prostate.
- C8-C18 Entire posterior right lobe, from apex to base.
- C19-C30 Entire posterior left lobe, from apex to base.

Intraoperative Consultation:

Date of Printing:

MR #:

Page 2 of 3

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

A1FS, lymph node, "left pelvic lymph node":
Negative for malignancy.

B1FS, lymph node, "right pelvic lymph node":
Negative for malignancy.
MD, Attending Physician

Date of Printing:

MR #:

Page 3 of 3

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file ce27f13b-6d67-47b4-89ea-3f463cc80b59 (TCGA-XJ-A83G.F5DB0EA7-336E-4A5E-9BFD-3291A5DB4D3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).